Surgical pathology report (de-identified scan), TCGA case TCGA-55-8090, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-8090-01A (Primary Tumor).

[page 1 of 2]
Surg Path Final Report

* Final Report *

* Final Report *

SURG PATH FINAL REPORT

SURGICAL PATHOLOGY

Collected:
Accession:
Physician:

PROCEDURE

Right thoracoscopy.

SPECIMEN:

Right lower lobe lung mass. Frozen section - check margins.

-year-old man, hx. of nonsmall cell carcinoma with hip and right lower lobe nodule.

HISTORY

Right lung mass.

GROSS

Specimen received in fresh for frozen section labeled as "right lower lobe lung mass," consists of a wedge of lung measuring 5 x 4 x 2.5 cm. By opening, the cut surface reveals a solid tan-white mass measuring 2.5 x 2 x 2 cm. The sutured margin is negative, 3 mm from tumor. The serosal surface appears involved by tumor. Representative section is processed for frozen section.

The specimen is submitted as follows:

1. Frozen control.
- 2-3. The tumor, the suture margin.

FROZEN SECTION DIAGNOSIS

Adenocarcinoma.

is notified for diagnosis at

MICROSCOPIC

Performed.

DIAGNOSIS

Right lower lobe of lung, wedgectomy:

Adenocarcinoma, moderately differentiated (2.5 cm). The tumor is limited in lung, associated with scar of subpleura.

Resection margins are negative for tumor.

Lymphovascular invasion is present.

COMMENT

Compare to left lower lung biopsy at the

Printed by:
Printed on:

Page 1 of 2
(Continued)

[page 2 of 2]
Surg Path Final Report

* Final Report *

tumor cells of two biopsies are morphologically similar.

Dr. [REDACTED] reviewed the case and concurs with the diagnosis.

[REDACTED] M.D. (Electronic Signature) [REDACTED]

Completed Action List:

* Order by [REDACTED] on [REDACTED]

Type:
Date:
Status:
Title:
Encounter info:

Printed by:
Printed on:

Page 2 of 2
(End of Report)

Source: NCI Genomic Data Commons file 8dbb6675-f23d-41ce-9ad3-48bb75567284 (TCGA-55-8090.8F75F207-FE12-44BA-86B2-444AB5578D45.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).